Surgical pathology report (de-identified scan), TCGA case TCGA-HU-8244, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-8244-01A (Primary Tumor).

Stomach, laparoscopic distal gastrectomy:

Early gastric carcinoma

(associated with high-grade adenoma, about 40% of the lesions)

(Muc2(-)/Muc5AC(-)/Muc6(-)/CD10(+)/cERB2(-), I type)

1. Location : middle third, Center at body, posterior wall
2. Gross type : EGC type 0-I+ IIa
3. Histologic type : tubular adenocarcinoma, well differentiated (tub1)
4. Histologic type by Lauren : intestinal
5. Growth pattern: not applicable
6. Size : 6.5x4.3cm
7. Depth of invasion : invades mucosa (muscularis mucosa) (pT1a)
8. Resection margin: free from carcinoma
safety margin: distal 3.7cm, proximal 0.6cm
9. Lymph node metastasis : no metastasis in 32 regional lymph nodes (pN0)
(lesser curvature 0/18 , greater curvature 0/14)
10. Lymphatic invasion : not identified
11. Venous invasion : not identified
12. Perineural invasion : not identified
13. Associated findings
- 1) foveolar hyperplasia with pit dysplasia
14. Pre-existing adenoma : Tubular adenoma high grade dysplasia

Stomach, surgical margin, distal, biopsy:

No tumor.

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

Source: NCI Genomic Data Commons file 0ca1386a-56c6-4e0c-aed3-a08f0c2a987e (TCGA-HU-8244.1407C2CD-4939-4779-B123-1B6E635A1362.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).